TCGA case TCGA-06-0185 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8f3acbbd-b2ca-4e66-8fe5-dbb49277f35b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 54.5 years (19,923 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 57 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Arsenic Trioxide; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 56 days; Number of cycles: 12; Treatment dose: 17 mg; Prescribed dose: 0.25; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 98 days; Days to treatment end: 249 days; Number of cycles: 6; Treatment dose: 370 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 739 days (2.0 years); Days to treatment end: 1,397 days (3.8 years); Number of cycles: 24; Treatment dose: 689 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 739 days (2.0 years); Days to treatment end: 1,397 days (3.8 years); Number of cycles: 24; Treatment dose: 232 mg; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cabozantinib S-malate; Initial disease status: Progressive Disease; Days to treatment start: 1,502 days (4.1 years); Days to treatment end: 1,636 days (4.5 years); Number of cycles: 2; Treatment dose: 75 mg/day; Prescribed dose: 75; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,664 days (4.6 years); Treatment dose: 791 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 1,670 days (4.6 years); Days to treatment end: 1,677 days (4.6 years); Treatment dose: 3,200 cGy; Course number: 2; Number of fractions: 4; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,986 days (5.4 years); Days to treatment end: 2,228 days (6.1 years); Number of cycles: 10; Treatment dose: 145 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 2,259 days (6.2 years); Number of cycles: 4; Treatment outcome: Treatment Ongoing; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 56.5 years (20,634 days); Days to diagnosis: 711 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 711 days (1.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 711 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to progression: 711 days (1.9 years).
- Days to follow up: 1,126 days (3.1 years); Disease response: With Tumor.
- Days to follow up: 2,246 days (6.1 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0185-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-06-0185-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-06-0185-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0185-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Regimen number: 01; Pharmaceutical therapy drug name: Arsenic Trioxide (ATO).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 04.
- Drug treatment 3: Regimen number: 06.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 5: Regimen number: 02.
- Drug treatment 7: Regimen number: 05.
- Drug treatment 8: Regimen number: 03; Pharmaceutical therapy drug name: XL184.
- Radiation treatment 2: Radiation type other: Fractionated stereotactic radiosurgery.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,246 days; disease-specific survival: no event (censored), 2,246 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 711 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0185-01A-01D-0236-01): tumor purity 0.79, ploidy 4.04, whole-genome doublings 1.
